Gene-level copy-number profile of tumor specimen TCGA-5M-AATE-01A from TCGA case TCGA-5M-AATE, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage IIA; Age at diagnosis: 76.3 years (27,870 days).
Specimen TCGA-5M-AATE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.66d2352f-05fb-40e7-8915-04df2cf0d502.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-5M-AATE-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/10f701e5-e6b9-4ca7-ac71-dd5c232ff5de

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 3,107; copy number 2: 6,067; copy number 3: 30,879; copy number 4: 9,606; copy number 5: 6,782; copy number 6: 1,925; copy number 9: 1,454.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-5M-AATE-01A-11D-A40O-01): tumor purity 0.65, ploidy 4.48, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,454 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr20:87,250–16,053,197, 291 genes, copy number 9 (within-gene range 6–9) (broad region; genes not listed).
- chr20:15,280,764–64,313,132, 1,163 genes, copy number 9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 3,107. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
